Somatic mutation profile of tumor specimen TCGA-59-2355-01A (aliquot TCGA-59-2355-01A-01W-0799-08) from TCGA case TCGA-59-2355, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3.
Specimen TCGA-59-2355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e67fd77-70a7-40e0-86fc-556123055074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2355-10A (Blood Derived Normal), aliquot TCGA-59-2355-10A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/412e2950-55fc-40be-8cac-648752262fdf

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 52/91 reads (57%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF18 | c.334G>A p.G112S (on ENST00000359920 / NM_001130955.2; = p.G8S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100148933; called by muse, mutect2
- ARHGEF9 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV53640922; called by muse, mutect2, varscan2
- ATN1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV63112067; called by muse, mutect2, varscan2
- CCAR1 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1283966281, COSV56271694; called by muse, mutect2, varscan2
- CPT1A | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs1435045544, COSV55758636; called by muse, mutect2, varscan2
- CSMD3 | c.8293C>A p.P2765T (on ENST00000297405 / NM_001363185.1; = p.P2596T on NM_052900.3) | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV52243545; called by muse, mutect2, varscan2
- CYP11B1 | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 216/384 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV52828839; called by muse, mutect2, varscan2
- DCC | c.3870C>A p.D1290E | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV101472318; called by muse, mutect2
- EIF2AK2 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779693187, COSV51797593; called by muse, mutect2, varscan2
- JPH1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60610700; called by muse, mutect2
- KIF5B | c.2189T>C p.I730T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1564463569, COSV100191376; called by muse, mutect2
- KL | c.1824G>C p.Q608H | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV66309379; called by muse, mutect2, varscan2
- MACF1 | c.17504C>G p.P5835R (on ENST00000372915; = p.P3877R on NM_012090.5) | Missense Mutation (SNP) | VAF 22/492 reads (4%) | catalogued as COSV99241134; called by muse, mutect2
- MYH6 | c.1509_1510insTAAC p.K504* | Nonsense Mutation (INS) | VAF 31/102 reads (30%) | catalogued as COSV100676281; called by pindel, varscan2
- PIGH | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs370375274; called by muse, mutect2, varscan2
- PYGM | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs765612286, CM071071, COSV51221834; called by muse, mutect2, varscan2
- SCNN1G | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55600252; called by muse, mutect2, varscan2
- UGGT2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778022471, COSV65076801; called by muse, mutect2, varscan2
- VARS2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057518559, COSV58913499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFYVE26 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 100/366 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as COSV61330970, COSV61332245; called by muse, mutect2, varscan2
- ARMC1 | c.528dup p.Q177Sfs*18 | Frame Shift Ins (INS) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 294/856 reads (34%) | called by mutect2, varscan2
- MYH6 | c.1502A>C p.E501A | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- RDM1 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 80/125 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CALR | c.675C>T p.I225= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs139658454, COSV57130781; called by muse, mutect2, varscan2
- EIF2B2 | c.1017G>A p.L339= | Silent (SNP) | VAF 66/743 reads (9%) | catalogued as COSV56720864; called by muse, mutect2
- LMNB2 | c.1524G>A p.L508= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1408420062, COSV53114784; called by muse, mutect2, varscan2
- PRAMEF15 | c.567T>A p.I189= | Silent (SNP) | VAF 114/790 reads (14%) | called by muse, varscan2
- PTBP2 | c.531C>T p.S177= (on ENST00000426398 / NM_001300986.2; = p.S169= on NM_021190.4) | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as rs769192340, COSV64626429; called by muse, mutect2
- SQOR | c.1344T>C p.G448= | Silent (SNP) | VAF 30/488 reads (6%) | catalogued as COSV99525497; called by muse, mutect2
- MAZ | c.1280-537G>C | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as COSV50716568; called by muse, mutect2, varscan2
